Gene-level copy-number profile of tumor specimen C3N-04098-01 (profiled together with C3N-04098-02) from CPTAC case C3N-04098, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.2 years (23,078 days).
Specimen C3N-04098-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 50324a90-1044-4aa9-ad27-cfd7ecea048d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04098-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/13f2bac4-f9a3-4496-ba13-091eb637ce18

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 30; copy number 2: 6,782; copy number 3: 1,381; copy number 4: 40,305; copy number 5: 3,507; copy number 6: 5,615; copy number 7: 138; copy number 8: 396; copy number 9: 6; copy number 10: 76; copy number 12: 52; copy number 14: 28; copy number 15: 26; copy number 22: 1; copy number 40: 3.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,590,487–248,635,091, 4 genes: OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr9:21,201,469–21,441,316, 21 genes: IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1.
- chr9:21,455,484–21,456,049, 1 gene (within-gene range 0–2): IFNWP19.
- chr9:21,638,285–22,455,740, 19 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr10:133,453,928–133,629,507, 7 genes (within-gene range 0–2): SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 192 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,744,176–41,308,565, 154 genes, copy number 10–15 (broad region; genes not listed).
- chr6:49,834,257–52,284,881, 28 genes, copy number 10: CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3.
- chr9:65,189,995–65,285,209, 4 genes, copy number 22–40: BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr12:59,322,765–59,524,184, 5 genes, copy number 9: AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448.
- chr19:20,432,552–20,571,095, 1 gene, copy number 9 (within-gene range 6–9): AC008554.1.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
